Somatic mutation profile of tumor specimen 0DLZOL from CCDI case PBBZYX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.5 years (556 days).
Specimen 0DLZOL: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ce72629-cc04-4a1d-86e6-5aa17a427acc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLZNF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a0d1831-8d0e-4283-b6b9-c586618e1c7f

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGBL1 | c.2692T>C p.C898R | Missense Mutation (SNP) | VAF 211/484 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66861853; called by muse, mutect2, varscan2
- RARA | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 199/447 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs1471663982; called by muse, mutect2, varscan2
- CTAG2 | c.492A>T p.K164N | Missense Mutation (SNP) | VAF 210/456 reads (46%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- HCN4 | c.1757G>A p.C586Y | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EZHIP | c.702C>T p.V234= | Silent (SNP) | VAF 354/797 reads (44%) | called by muse, mutect2, varscan2
